Gene-level copy-number profile of tumor specimen TCGA-24-2293-01A from TCGA case TCGA-24-2293, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Specified parts of peritoneum; Tumor grade: G3; Age at diagnosis: 47.2 years (17,235 days).
Specimen TCGA-24-2293-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.a8a9d81b-94c8-47b7-a261-4611c6fbabe0.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-24-2293-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9ab998b5-49db-4bee-86e2-d6ea0ae9a9a2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 18; copy number 1: 1,546; copy number 2: 23,814; copy number 3: 21,409; copy number 4: 10,550; copy number 5: 1,791; copy number 6: 251; copy number 7: 266; copy number 8: 118; copy number 9: 54.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-24-2293-01A-01D-0704-01): tumor purity 0.39, ploidy 2.81, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 18 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:60,459,848–60,945,073, 13 genes: SETP21, AC109486.2, PART1, AC109486.3, AC016591.1, DEPDC1B, CAB39P1, AC109133.1, KRT8P31, ELOVL7, ERCC8, GNL3LP1, ERCC8-AS1.
- chr18:5,954,706–6,415,237, 1 gene (within-gene range 0–2): L3MBTL4.
- chr18:6,017,723–6,398,020, 4 genes: RNU5F-3P, L3MBTL4-AS1, MIR4317, AP005060.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,480 genes in 27 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:93,079,235–94,541,759, 38 genes, copy number 5: MTF2, TMED5, CCDC18, AC126124.2, AC126124.1, CCDC18-AS1, AL139421.1, DR1, AL137159.1, Y_RNA, FNBP1L, RNA5SP53, BCAR3, BCAR3-AS1, MIR760, AL049796.1, DNTTIP2, GCLM, CHCHD2P5, MTND4P11, MTND3P21, MTCO3P21, MTATP6P13, AL117351.2, MTCO2P21, MTCO1P21, AL117351.1, ABCA4, AC093579.1, ARHGAP29, RN7SL440P, ARHGAP29-AS1, GAPDHP29, AC097059.1, AC118469.1, AC118469.2, ABCD3, F3.
- chr1:110,272,484–110,674,940, 17 genes, copy number 5: AL137790.1, RBM15-AS1, RBM15, LAMTOR5-AS1, SLC16A4, AL355488.1, LAMTOR5, PROK1, AL358215.1, AL358215.2, AL358215.3, CYMP, CYMP-AS1, KCNA10, KCNA2, AL365361.1, KCNA3.
- chr1:203,626,787–204,562,521, 35 genes, copy number 6: ATP2B4, NSA2P1, SNORA77, LAX1, ZC3H11A, ZBED6, AC114402.2, AC114402.1, RPL35AP5, SNRPE, KRT8P29, HSPE1P6, CBX1P3, AC096645.1, LINC00303, AL592146.2, SOX13, AL592146.1, ETNK2, ERLNC1, REN, AL592114.2, KISS1, GOLT1A, PLEKHA6, AL592114.3, AL592114.1, LINC00628, AL606489.1, AL606489.2, PPP1R15B, PIK3C2B, MDM4, AL512306.1, RNA5SP74.
- chr2:101,696,850–102,240,002, 7 genes, copy number 5 (within-gene range 3–5): MAP4K4, LINC01127, IL1R2, AC007271.1, IL1R1, IL1R1-AS1, IL1RL2.
- chr3:47,585,269–47,782,106, 1 gene, copy number 6 (within-gene range 2–6): SMARCC1.
- chr3:47,663,626–48,328,341, 23 genes, copy number 6: HIGD2AP2, DHX30, AC026318.1, MIR1226, MAP4, Y_RNA, VPS26BP1, AC124916.2, RN7SL664P, AC124916.1, CDC25A, SNRPFP4, RNU7-128P, NDUFB1P1, MIR4443, CAMP, ZNF589, MRPS18AP1, Y_RNA, NME6, FCF1P2, SPINK8, MIR2115.
- chr3:169,083,499–170,396,835, 33 genes, copy number 9 (within-gene range 4–9): MECOM, MECOM-AS1, RPL22P1, AC007849.1, SDHDP3, RNU6-637P, TERC, Telomerase-vert, ACTRT3, AC078802.1, MYNN, AC078795.1, LRRC34, AC078795.3, AC078795.2, LRRIQ4, LRRC31, KRT18P43, SAMD7, AC008040.2, AC008040.1, AC008040.3, SEC62, SEC62-AS1, GPR160, RNU4-38P, KMT5AP3, PHC3, RNU6-315P, PRKCI, Y_RNA, AC073288.1, SKIL.
- chr6:38,675,925–39,934,551, 23 genes, copy number 5–9 (within-gene range 2–9): GLO1, AL391415.1, DNAH8, RN7SL465P, AL035555.2, AL035555.1, DNAH8-AS1, AL034345.1, AL035690.1, GLP1R, SAYSD1, ANKRD18EP, KCNK5, KCNK17, KCNK16, KIF6, AL136087.1, E2F4P1, RNU1-54P, DAAM2, AL592158.1, DAAM2-AS1, MOCS1.
- chr7:30,580,533–31,658,720, 17 genes, copy number 6 (within-gene range 4–6): GARS1, CRHR2, INMT, AC006022.1, INMT-MINDY4, MINDY4, AC004691.1, AC004691.2, AQP1, GHRHR, ADCYAP1R1, AC006466.1, AC006398.1, AC006380.1, NEUROD6, AC005090.1, ITPRID1.
- chr7:57,599,794–73,832,693, 310 genes, copy number 5 (broad region; genes not listed).
- chr8:57,594,166–58,659,853, 18 genes, copy number 8 (within-gene range 3–8): AC104051.1, AC104051.2, LINC01602, AC012103.1, FAM110B, AC104350.1, AC027698.1, RPL26P26, AC092819.3, AC092819.1, AC092819.2, UBXN2B, AC009927.1, CYP7A1, PPIAP85, SDCBP, NSMAF, AC068522.1.
- chr8:119,832,875–139,704,109, 257 genes, copy number 5–8 (broad region; genes not listed).
- chr8:140,505,813–145,066,685, 202 genes, copy number 5 (broad region; genes not listed).
- chr9:127,690,098–127,814,327, 12 genes, copy number 6: AL162426.1, PTRH1, MIR3911, CFAP157, TTC16, TOR2A, SH2D3C, AL162586.2, CDK9, MIR3960, MIR2861, FPGS.
- chr9:127,816,066–127,832,743, 2 genes, copy number 6: AL162586.1, Y_RNA.
- chr10:6,779,549–8,461,863, 24 genes, copy number 5 (within-gene range 3–5): LINC00707, AL392086.1, AL392086.3, LINC02665, AL590095.1, SFMBT2, COX6CP17, AL139125.1, LINC02642, RNU6-535P, AL445070.1, ITIH5, ITIH2, KIN, ATP5F1C, TAF3, AL353754.1, GATA3, GATA3-AS1, AL390294.1, PRPF38AP1, LINC00708, AL390835.1, AC025946.1.
- chr10:12,877,459–15,171,278, 60 genes, copy number 5: AL353586.1, CCDC3, RNA5SP300, RPL5P25, OPTN, SNRPGP5, AL355355.2, AL355355.1, BTBD7P1, RPL36AP36, MCM10, RNU6-6P, UCMA, PHYH, RBISP1, SEPHS1, AL355870.2, AL355870.1, BEND7, Y_RNA, AL590677.1, PRPF18, RPL6P24, AL157392.5, AL157392.3, FRMD4A, AL157392.4, AL157392.1, RNA5SP301, AL157392.2, NUTF2P5, AC044781.1, AL157896.1, AL139405.1, MIR4293, Metazoa_SRP, MIR1265, FAM107B, AL158168.1, RNA5SP302, RPSAP7, CDNF, AC069544.2, HSPA14, AC069544.1, SUV39H2, DCLRE1C, MEIG1, OR7E110P, OR7E26P, OR7E115P, DCLRE1CP1, OLAH, ACBD7, GAPDHP45, RPP38-DT, RPP38, NMT2, PPIAP30, AL590365.1.
- chr10:29,289,061–31,707,388, 48 genes, copy number 5 (within-gene range 3–5): LYZL1, AL158167.1, SVIL-AS1, PTCHD3P1, SVIL, MIR604, SNORD115, MIR938, CKS1BP2, RNU6-908P, AL353093.1, JCAD, RNU6-598P, EEF1A1P39, AL353796.1, MTPAP, AL353796.2, DNM1P17, GOLGA2P6, RN7SL241P, MIR7162, NIFKP1, AL161651.1, CCND3P1, MAP3K8, HNRNPA1P32, AL590068.4, AL590068.1, RN7SL63P, AL590068.2, AL590068.3, LYZL2, SVIL2P, LINC02644, ZNF438, AL359532.1, DDX10P1, AL359546.1, LINC02664, ZEB1-AS1, RNA5SP309, ZEB1, SPTLC1P1, AL117340.1, AL161935.1, AL161935.3, AL161935.2, MACORIS.
- chr10:36,432,882–70,568,450, 514 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr12:12,049,844–12,267,044, 5 genes, copy number 7 (within-gene range 4–7): BCL2L14, PTMAP9, MIR1244-4, LRP6, AC007537.1.
- chr14:93,718,298–94,130,253, 13 genes, copy number 6: PRIMA1, AL132642.2, FAM181A-AS1, FAM181A, ASB2, AL132642.1, MIR4506, CCDC197, OTUB2, DDX24, IFI27L1, IFI27, IFI27L2.
- chr19:4,153,631–5,340,803, 54 genes, copy number 5 (within-gene range 3–5): CREB3L3, SIRT6, ANKRD24, EBI3, AC005578.1, YJU2, SHD, TMIGD2, FSD1, STAP2, AC104521.1, MPND, AC007292.3, EIF1P6, AC007292.2, SH3GL1, AC007292.1, CHAF1A, AC011498.3, UBXN6, MIR4746, AC011498.2, AC011498.7, AC011498.6, AC011498.1, HDGFL2, PLIN4, PLIN5, AC011498.4, LRG1, SEMA6B, AC011498.5, TNFAIP8L1, MYDGF, AC005339.1, DPP9, DPP9-AS1, AC005594.1, MIR7-3HG, MIR7-3, AC005523.1, FEM1A, AC005523.2, TICAM1, AC027319.1, PLIN3, ARRDC5, UHRF1, MIR4747, KDM4B, PTPRS, AC022517.1, RPL32P34, AC005790.1.
- chr19:8,322,584–9,675,100, 64 genes, copy number 5–8 (within-gene range 2–8) (broad region; genes not listed).
- chr20:87,250–4,740,668, 148 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr20:5,126,879–16,053,197, 133 genes, copy number 7 (within-gene range 3–7) (broad region; genes not listed).
- chr21:43,461,960–44,711,572, 74 genes, copy number 7 (within-gene range 3–7) (broad region; genes not listed).
- chr22:21,103,016–26,968,763, 348 genes, copy number 5–8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,546. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
